Somatic mutation profile of tumor specimen MMRF_1231_1_BM_CD138pos (aliquot MMRF_1231_1_BM_CD138pos_T2_TSE61_L00075) from MMRF case MMRF_1231, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.4 years (28,276 days).
Specimen MMRF_1231_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84d2f803-b1be-4e5d-b8bc-d73da27a6e6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1231_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1231_1_PB_Whole_C1_TSE61_L00076; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75c56f80-6b2a-41cd-b436-8ff6ececfbbd

The open-access MAF lists 54 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, 3'UTR 14, 5'UTR 4, Silent 4, Frame Shift Del 2, 5'Flank 2, Intron 2, RNA 2, Nonsense Mutation 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 39/126 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 29/162 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CRLF3 | c.1268G>A p.C423Y | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV60836208; called by muse, mutect2, varscan2
- CXCR4 | c.197A>G p.Q66R | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.248); catalogued as rs1428775677; called by muse, mutect2, varscan2
- NEK11 | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63578267; called by muse, mutect2, varscan2
- PCDHA1 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 105/435 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV65372722; called by muse, mutect2, varscan2
- SDK1 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 130/266 reads (49%) | catalogued as rs1453149219, COSV67367328; called by muse, mutect2, varscan2
- SEMA3B | c.1720G>T p.A574S | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.96); PolyPhen benign (0.013); catalogued as COSV100312703; called by muse, mutect2, varscan2
- SLC19A3 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1347868865, COSV51453239; called by muse, mutect2, varscan2
- SLC24A4 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.177); catalogued as rs200041150; called by muse, mutect2, varscan2
- TRIM44 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1414448837; called by muse, mutect2
- TTN | c.86878G>T p.A28960S (on ENST00000591111; = p.A21536S on NM_003319.4) | Missense Mutation (SNP) | VAF 3/38 reads (8%) | PolyPhen probably damaging (0.996); catalogued as COSV60222489; called by muse, mutect2
- USP30 | c.707A>G p.H236R | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.017); catalogued as rs1379253469; called by muse, mutect2, varscan2
- BAG1 | c.782T>A p.F261Y | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DSP | c.8525G>A p.R2842H | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- DYNC2H1 | c.6466del p.V2156Ffs*2 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- GYS2 | c.1018_1021dup p.I341Rfs*18 | Frame Shift Ins (INS) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- LETM2 | c.1342A>C p.T448P (on ENST00000379957 / NM_001286819.2; = p.T353P on NM_144652.3) | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEK1 | c.3506G>A p.S1169N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR2J2 | c.75A>T p.E25D | Missense Mutation (SNP) | VAF 116/278 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM15B | c.2258A>T p.D753V | Missense Mutation (SNP) | VAF 142/312 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- RNF17 | c.438T>A p.N146K | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC27A3 | c.469C>G p.L157V (on ENST00000271857; = p.L29V on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP37 | c.860_863del p.D287Gfs*29 | Frame Shift Del (DEL) | VAF 51/92 reads (55%) | called by mutect2, pindel, varscan2
- ZNF226 | c.2264A>T p.Y755F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- EVI5L | c.303G>C p.R101= | Silent (SNP) | VAF 52/120 reads (43%) | called by muse, mutect2
- TANGO6 | c.3066G>A p.V1022= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as COSV55765668; called by muse, mutect2, varscan2
- TCFL5 | c.1335A>G p.A445= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs1043903082; called by muse, mutect2, varscan2
- ZRANB3 | c.2154T>C p.G718= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as rs754885188; called by muse, mutect2, varscan2
- AGO3 | c.-112C>T | 5'UTR (SNP) | VAF 49/89 reads (55%) | catalogued as rs936511307; called by muse, mutect2, varscan2
- BMS1 | c.*2765G>C | 3'UTR (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2, varscan2
- CCSER1 | c.2011-34048C>G | Intron (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- CILP | c.-61A>T | 5'UTR (SNP) | VAF 33/89 reads (37%) | called by muse, mutect2, varscan2
- CLOCK | c.*1417T>C | 3'UTR (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- CLYBL | chr13:99897050 del G | 3'Flank (DEL) | VAF 100/242 reads (41%) | called by mutect2, pindel, varscan2
- CNEP1R1 | c.*522T>G | 3'UTR (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- COPS9 | chr2:240136318 C>T | 5'Flank (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- CTDSPL2 | c.*1097C>A | 3'UTR (SNP) | VAF 63/161 reads (39%) | called by muse, mutect2, varscan2
- DIO2 | c.*4857G>A | 3'UTR (SNP) | VAF 61/127 reads (48%) | called by muse, mutect2, varscan2
- ETF1 | c.*966T>C | 3'UTR (SNP) | VAF 15/151 reads (10%) | called by muse, mutect2
- GRIA2 | c.*975G>C | 3'UTR (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- HMGB1P1 | n.541dup | RNA (INS) | VAF 80/181 reads (44%) | called by mutect2, pindel, varscan2
- MCHR2 | c.-94C>T | 5'UTR (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- MIPOL1 | c.*225G>T | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- MIR143 | chr5:149424105 C>A | 5'Flank (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- NORAD | n.174G>A | RNA (SNP) | VAF 22/73 reads (30%) | catalogued as rs1279950661; called by muse, mutect2, varscan2
- PLEKHM3 | c.*356C>A | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- RBFOX2 | c.*4796T>A | 3'UTR (SNP) | VAF 41/76 reads (54%) | called by muse, mutect2, varscan2
- RBPMS | c.*1583A>G | 3'UTR (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- SLC7A8 | c.508+10983C>T | Intron (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
- UGT2A3 | c.*619dup | 3'UTR (INS) | VAF 10/87 reads (11%) | catalogued as rs1159359597; called by mutect2, pindel, varscan2
- UPP2 | c.-66A>G | 5'UTR (SNP) | VAF 45/97 reads (46%) | called by muse, mutect2, varscan2
- USP22 | c.*1564G>T | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- ZNF792 | c.*733A>T | 3'UTR (SNP) | VAF 81/169 reads (48%) | called by muse, mutect2, varscan2
